CCDI case PBCWPD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/c115485e-2795-4573-98d3-6625ca563ad0

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1KO9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1KOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1KOW: Tissue type: Tumor; Specimen type: Solid Tissue.
